Somatic mutation profile of tumor specimen MP2PRT-PAUXGE-TMP1-A (aliquot MP2PRT-PAUXGE-TMP1-A-1-0-D-A82M-36) from MP2PRT case MP2PRT-PAUXGE, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.6 years (1,689 days).
Specimen MP2PRT-PAUXGE-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 32efde8c-5a1e-4569-be1d-950462da446e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAUXGE-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAUXGE-NB1-A-1-0-D-A82M-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2dc790ff-4bda-4204-9b0f-a074244ff3b6

The open-access MAF lists 11 somatic variants for this specimen: 7 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, Silent 3, Intron 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DRP2 | c.43C>T p.R15* | Nonsense Mutation (SNP) | VAF 116/476 reads (24%) | catalogued as rs756695526; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GJB4 | c.680G>A p.R227Q | Missense Mutation (SNP) | VAF 51/363 reads (14%) | SIFT tolerated (0.57); PolyPhen benign (0.006); catalogued as rs768318044; called by muse, mutect2, varscan2
- PRICKLE2 | c.496C>T p.R166C (on ENST00000295902; = p.R110C on NM_198859.4) | Missense Mutation (SNP) | VAF 43/396 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs750086425, COSV99897782; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TRAV1-2 | c.89C>T p.T30M | Missense Mutation (SNP) | VAF 85/284 reads (30%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs1063358; called by muse, mutect2, varscan2
- IKZF1 | c.475A>T p.N159Y | Missense Mutation (SNP) | VAF 442/857 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- IL24 | c.509T>G p.F170C | Missense Mutation (SNP) | VAF 34/255 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by mutect2, varscan2
- NOX4 | c.662C>A p.T221N | Missense Mutation (SNP) | VAF 81/309 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0.096); called by muse, mutect2, varscan2
- ASB4 | c.336C>T p.H112= | Silent (SNP) | VAF 36/448 reads (8%) | catalogued as rs556456967; called by muse, mutect2
- MKRN3 | c.153G>A p.A51= | Silent (SNP) | VAF 135/503 reads (27%) | catalogued as rs759147640, COSV100090750, COSV58809735; ClinVar: likely benign; called by muse, mutect2, varscan2
- PCDHB15 | c.1893C>T p.S631= | Silent (SNP) | VAF 214/830 reads (26%) | called by muse, mutect2, varscan2
- KCNQ1 | c.1514+37594C>T | Intron (SNP) | VAF 29/895 reads (3%) | catalogued as rs1026855452; called by muse, mutect2
